Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5331, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5331-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Oral-Cavity: portion maxilla
2. Oral-Cavity: deep mucosal margin
3. Oral-Cavity: posterior margin
4. Oral-Cavity: medial margin

Diagnosis

1. Right maxillectomy.
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumour dimension: 2.2 cm.
- b. Maximum tumour thickness: 0.8 cm.
- c. The margins are negative for tumour (> 0.5 cm).
- d. No lymphovascular invasion or perineural invasion is identified.
- e. Bone sections are pending; an addendum will be issued.
2. Deep mucosal margin biopsy.
- Negative for malignancy.
3. Posterior margin biopsy.
- Negative for malignancy.
4. Medial margin biopsy.
- Negative for malignancy.

Synoptic Data

Specimen Type:	Resection: Right maxillectomy
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 2.2 cm
	Tumor thickness: 0.8 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	None identified
Margins:	Margins uninvolved by tumor

[page 2 of 3]
Surgical Pathology Consultation Report

Pathologic Staging (pTNM):

pTX: Primary tumor of lip or oral cavity cannot be assessed
pNX: Regional lymph nodes cannot be assessed for aerodigestive sites
pMX: Distant metastasis cannot be assessed

Comment

The T stage is deferred in the synoptic report as the bone is still pending decalcification.

Gross Description

1. The specimen is labeled with the patient's name and as Oral Cavity: Portion maxilla. It consists of a portion of right maxilla measuring 5.0 AP x 2.0 SI x 3.1 ML cm. It includes a portion of gingiva and roof of mouth/palate with four teeth. There is a tumor arising in the roof of mouth extending into the alveolar ridge going into the gingiva. The tumor measures 2.2 AP x 0.8 SI x 2.1 ML cm. The tumor is solid in consistency and tan-brown in color. There is gross involvement of bone by the tumour. The tumor is located at 0.5 cm from the closest superior gingival margin. Remaining margins are as follows: Anterior gingival margin 2.3 cm; posterior gingival margin-1.1 cm; posterior palate margin-0.8 cm; medial palate margin 0.7 cm. Representative sections are submitted.

1A- superior gingival margin
1B- anterior gingival margin
1C- posterior gingival margin
1D- posterior palate margin
1E- medial palate margin
1F-1G- tumor
1H- normal gingiva and palate
1I- anterior maxilla margin
1J- posterior maxilla margin
1K-1L- superior maxillary margin
1M- medial maxillary margin.
1N-1O- mid maxilla with tumor.

Three pieces of tumor/one piece normal were taken for tissue bank.

2. The specimen container is labeled with the patient's name and as "Oral Cavity: Deep mucosal margin". It consists of a fragment of tissue measuring 1.4 x 0.5 x 0.3 cm.

2A- specimen in toto.

3. The specimen container is labeled with the patient's name and as "Oral Cavity: Posterior margin". It consists of a fragment of tissue measuring 0.9 x 0.3 x 0.2 cm.

3A- specimen in toto.

4. The specimen container is labeled with the patient's name and as "Oral Cavity: Medial margin". It consists of a fragment of tissue measuring 0.6 x 0.3 x 0.2 cm.

4A- specimen in toto.

Addendum

[page 3 of 3]
Addendum Comment

1. Maxilla (bone sections)

- The tumour is present directly adjacent to bone but without invasion.
- The maxillary bone margins are negative for tumour.
- Tumour is present in the soft tissue adjacent to the superior bone margin.
- The tumour is staged as pT2 – tumour more than 2 cm but not more than 4 cm in greatest dimension.
-

Source: NCI Genomic Data Commons file 332695c1-5413-4847-86e5-6be31107d4a8 (TCGA-CQ-5331.8790C966-542B-4B1E-A1E4-2CE75D1DF4E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).